Somatic mutation profile of tumor specimen C3L-03394-03 (aliquot CPT0224460007) from CPTAC case C3L-03394, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 66.0 years (24,110 days).
Specimen C3L-03394-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df7fa7ff-2885-43bd-bb71-02b49f0681c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03394-31 (Blood Derived Normal), aliquot CPT0226210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9aea0d53-bd64-435f-9311-f328339b7c32

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.979A>T p.M327L | Missense Mutation (SNP) | VAF 19/433 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as rs1439365497; called by muse, mutect2
- DNAH11 | c.12145C>T p.P4049S | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV60967105; called by muse, mutect2
- EGF | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 18/580 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954524553, COSV54485852, COSV99491572; called by muse, mutect2
- CECR2 | c.989A>C p.K330T (on ENST00000342247 / NM_001290047.2; = p.K167T on NM_001290046.1) | Missense Mutation (SNP) | VAF 17/495 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- COL6A6 | c.2781T>A p.D927E | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2
- SMG8 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 92/329 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1B | c.2700G>A p.P900= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- PACS2 | c.2085C>T p.D695= | Silent (SNP) | VAF 17/319 reads (5%) | catalogued as rs139536717, COSV57652912; called by muse, mutect2
- SLC7A9 | c.1095T>C p.Y365= | Silent (SNP) | VAF 16/532 reads (3%) | called by muse, mutect2
- YAE1 | c.531G>A p.G177= | Silent (SNP) | VAF 18/336 reads (5%) | called by muse, mutect2
- CHRNB3 | c.-9G>A | 5'UTR (SNP) | VAF 46/345 reads (13%) | called by muse, varscan2
- MLX | c.*1100G>A | 3'UTR (SNP) | VAF 12/312 reads (4%) | catalogued as rs956068670; called by muse, mutect2
